Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAF6, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAF6-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address :

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 6 cm; tumor confined to testis in available slides; no angio-invasion; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

ICD O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
JW 3/13/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file edcb2c96-17bb-4863-b4e5-8b37be45ea61 (TCGA-2G-AAF6.5892E026-307B-4A38-972F-92DF6ACF0A90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).